Gene-level copy-number profile of tumor specimen C3N-04693-01 from CPTAC case C3N-04693, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.5 years (19,913 days).
Specimen C3N-04693-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 906c5aa7-5604-4da0-b7b3-a3280dac87c9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04693-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/f7dd5dcf-001f-4d51-a8bf-90d446ac4561

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 12; copy number 2: 6,507; copy number 3: 59; copy number 4: 48,727; copy number 5: 76; copy number 6: 2,937; copy number 7: 2; copy number 8: 1; copy number 12: 11; copy number 46: 37; copy number 47: 2.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:138,161,939–138,422,197, 6 genes (within-gene range 0–2): ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2.
- chr6:138,435,213–138,464,383, 2 genes (within-gene range 0–2): MIR3145, AL391669.1.
- chr9:10,532,145–10,948,481, 6 genes (within-gene range 0–2): AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–2): AL449423.1, CDKN2B, UBA52P6.
- chr10:87,863,625–88,585,733, 8 genes (within-gene range 0–2): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 50 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:90,915,298–91,906,335, 11 genes, copy number 12: ZNF644, RPL5P6, HFM1, Y_RNA, FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P, TGFBR3, RN7SL653P.
- chr1:191,858,707–191,890,229, 1 gene, copy number 46 (within-gene range 4–46): AL359081.1.
- chr1:203,861,599–205,084,460, 36 genes, copy number 46: SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81.
- chr20:142,590–159,163, 2 genes, copy number 47: DEFB126, DEFB127.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
